Somatic mutation profile of tumor specimen 0DSW9Z from CCDI case PBCILX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 2.4 years (888 days).
Specimen 0DSW9Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75287f11-ac5d-4c0f-a4ce-2364b238f371.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSW9I (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/020ded86-d708-40b3-b423-5e22e9b3fde5

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 1, Frame Shift Ins 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMP1 | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 142/322 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTCH1 | c.3127_3128dup p.V1045Lfs*5 | Frame Shift Ins (INS) | VAF 277/338 reads (82%) | called by mutect2, varscan2
- FGL2 | c.639C>T p.C213= | Silent (SNP) | VAF 32/957 reads (3%) | called by muse, mutect2
- PIK3CG | c.2652C>T p.D884= | Silent (SNP) | VAF 158/714 reads (22%) | catalogued as rs755002463, COSV63248548; called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 28/646 reads (4%) | called by muse, mutect2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 7/47 reads (15%) | called by muse, varscan2
